Somatic mutation profile of tumor specimen 0DKRD2 from CCDI case PBBYJZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid sarcoma; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 17.0 years (6,209 days).
Specimen 0DKRD2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 232b064c-7ae4-4a20-8553-857cd01dad0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKRCD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ae35b66-ac42-4dd4-a085-059990bdd449

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, Intron 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNBD1 | c.1212G>C p.E404D | Missense Mutation (SNP) | VAF 71/649 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73072709; called by muse, mutect2, varscan2
- FLNA | c.5482G>A p.V1828M (on ENST00000369850 / NM_001110556.2; = p.V1820M on NM_001456.3) | Missense Mutation (SNP) | VAF 180/870 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs782448596; ClinVar: uncertain significance; called by muse, varscan2
- MYLK2 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 90/946 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs770237487; ClinVar: uncertain significance; called by muse, mutect2
- RIPOR3 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 98/895 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs377763720, COSV99078765; called by muse, mutect2, varscan2
- ARID4B | c.3336C>G p.A1112= | Splice Region (SNP) | VAF 60/678 reads (9%) | called by muse, mutect2
- CFAP61 | c.1573G>C p.V525L | Missense Mutation (SNP) | VAF 79/993 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.106); called by muse, mutect2
- NPM1 | c.649T>G p.S217A | Missense Mutation (SNP) | VAF 102/1098 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.137); called by muse, mutect2
- OLFM2 | c.161G>C p.S54T | Missense Mutation (SNP) | VAF 120/904 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLCZ1 | c.470T>C p.M157T | Missense Mutation (SNP) | VAF 62/772 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNBD1 | c.1083T>C p.Y361= | Silent (SNP) | VAF 43/470 reads (9%) | called by muse, mutect2
- GRIN2A | c.3444G>A p.P1148= | Silent (SNP) | VAF 127/1055 reads (12%) | catalogued as rs1192386958, COSV58024912, COSV58027288; called by muse, mutect2, varscan2
- KCNAB3 | c.576C>T p.Y192= | Silent (SNP) | VAF 49/962 reads (5%) | catalogued as rs373186210; called by muse, mutect2
- SLC40A1 | c.498C>T p.D166= | Silent (SNP) | VAF 64/868 reads (7%) | called by muse, mutect2
- SPACA4 | c.237C>T p.Y79= | Silent (SNP) | VAF 78/683 reads (11%) | called by muse, mutect2, varscan2
- ZNF318 | c.5304G>A p.E1768= | Silent (SNP) | VAF 54/532 reads (10%) | catalogued as rs1462882366; called by muse, mutect2
- CCL14 | c.79+884G>C | Intron (SNP) | VAF 38/262 reads (15%) | called by muse, varscan2
- OR5AR1 | c.-10A>C | 5'UTR (SNP) | VAF 23/168 reads (14%) | catalogued as rs1310204960; called by muse, mutect2, varscan2
- UBE2V1 | c.171+478_171+479del | Intron (DEL) | VAF 72/792 reads (9%) | called by mutect2, pindel
